Somatic mutation profile of tumor specimen TCGA-EM-A22L-01A (aliquot TCGA-EM-A22L-01A-11D-A17V-08) from TCGA case TCGA-EM-A22L, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 33.1 years (12,092 days).
Specimen TCGA-EM-A22L-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0995f790-172f-4eb1-bee9-81d31331d6da.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EM-A22L-10A (Blood Derived Normal), aliquot TCGA-EM-A22L-10A-01D-A17V-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3c7dcdf7-5fab-4fd3-b4e8-8c1d57e1f0f4

The open-access MAF lists 8 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 66/178 reads (37%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- GPR87 | c.950T>C p.M317T | Missense Mutation (SNP) | VAF 52/111 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.084); catalogued as rs746334545, COSV53464206; called by muse, mutect2, varscan2
- HMCN1 | c.15083T>C p.F5028S | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54931163; called by muse, mutect2, varscan2
- PROS1 | c.599A>T p.K200I | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.055); catalogued as COSV62399379; called by muse, mutect2, varscan2
- SCEL | c.959C>G p.T320S (on ENST00000349847 / NM_144777.3; = p.T300S on NM_003843.4) | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.311); catalogued as COSV62994334; called by muse, mutect2, varscan2
- STAG3 | c.1402C>T p.R468C | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as rs539912996, COSV57933950; called by muse, mutect2, varscan2
- VWF | c.6027C>A p.H2009Q | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.11); catalogued as COSV54631084; called by muse, mutect2, varscan2
- GUK1 | c.-3+505C>G | Intron (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2
